Somatic mutation profile of tumor specimen TARGET-30-PARJEN-01A (aliquot TARGET-30-PARJEN-01A-01D) from TARGET case TARGET-30-PARJEN, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 2.0 years (727 days).
Specimen TARGET-30-PARJEN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cac0531a-513c-4d3f-99c0-f9b9db57e765.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PARJEN-14A (Bone Marrow Normal), aliquot TARGET-30-PARJEN-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc07e128-6571-41f4-b0ef-a0827300a7f1

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB11 | c.1582A>G p.I528V | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0.036); catalogued as CD103544; called by muse, mutect2
- ADAM29 | c.1811G>A p.C604Y | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63660916; called by muse, mutect2, varscan2
- C2orf16 | c.7C>G p.L3V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as COSV68840179; called by muse, mutect2, varscan2
- DIS3L | c.1799A>T p.N600I (on ENST00000319212 / NM_001143688.3; = p.N517I on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.242); catalogued as COSV59911202; called by muse, mutect2, varscan2
- IRS4 | c.1963C>G p.L655V | Missense Mutation (SNP) | VAF 12/240 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- ATP8B3 | c.177C>A p.G59= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as COSV50084755; called by muse, mutect2
- NEK9 | c.1455C>A p.V485= | Silent (SNP) | VAF 45/169 reads (27%) | catalogued as COSV53132598; called by muse, mutect2, varscan2
- OR52H1 | c.-11C>A | 5'UTR (SNP) | VAF 24/75 reads (32%) | catalogued as COSV59505967; called by muse, mutect2, varscan2
